Somatic mutation profile of tumor specimen TCGA-G8-6325-01A (aliquot TCGA-G8-6325-01A-11D-2210-10) from TCGA case TCGA-G8-6325, project TCGA-DLBC (Lymphoid Neoplasm Diffuse Large B-cell Lymphoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Diffuse large B-cell lymphoma, NOS; Tissue or organ of origin: Intra-abdominal lymph nodes; Age at diagnosis: 69.1 years (25,256 days).
Specimen TCGA-G8-6325-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2f97457e-2a40-492e-a911-e5ce9e28bdcc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G8-6325-10A (Blood Derived Normal), aliquot TCGA-G8-6325-10A-01D-2210-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/edcbe4d4-6c00-4de6-a88e-e7d8615db395

The open-access MAF lists 83 somatic variants for this specimen: 55 protein-altering or splice-affecting, 26 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, Silent 26, Frame Shift Del 3, Splice Site 2, Nonsense Mutation 2, 3'UTR 1, Splice Region 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC004593.2 | c.1121G>A p.R374Q | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.024); catalogued as rs775178372, COSV99764392; called by muse, mutect2, varscan2
- BTBD16 | c.19-1G>T p.X7_splice | Splice Site (SNP) | VAF 17/127 reads (13%) | catalogued as rs1182124132; called by muse, mutect2, varscan2
- C2orf78 | c.2507G>A p.R836Q | Missense Mutation (SNP) | VAF 15/120 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs539780072, COSV68516997; called by muse, mutect2, varscan2
- CCDC146 | c.1084C>T p.R362* | Nonsense Mutation (SNP) | VAF 12/94 reads (13%) | catalogued as rs371350411; called by muse, mutect2, varscan2
- CCNB3 | c.3533C>T p.T1178I | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.37); catalogued as COSV52076713; called by muse, mutect2, varscan2
- CFHR5 | c.383C>T p.S128L | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.067); catalogued as rs774353375, COSV56817855; called by mutect2, varscan2
- CNTN1 | c.125T>C p.I42T | Missense Mutation (SNP) | VAF 32/194 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as rs750317692; called by muse, mutect2, varscan2
- EDNRA | c.1003G>A p.E335K | Missense Mutation (SNP) | VAF 28/162 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.657); catalogued as rs771470596, COSV60098975; called by muse, mutect2, varscan2
- FAM172A | c.78T>A p.D26E | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT tolerated, low confidence (0.83); PolyPhen benign (0.013); catalogued as rs1260261380; called by muse, mutect2, varscan2
- H1-3 | c.239G>T p.R80L | Missense Mutation (SNP) | VAF 53/268 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs779646561, COSV55098335; called by muse, mutect2, varscan2
- HK2 | c.1525G>A p.V509I | Missense Mutation (SNP) | VAF 21/190 reads (11%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.974); catalogued as rs763634644, COSV51873897; called by muse, mutect2, varscan2
- KLF2 | c.824G>A p.S275N | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.691); catalogued as rs1204502415, COSV50179841, COSV99934120; called by muse, mutect2, varscan2
- LTBP1 | c.3701C>T p.S1234L (on ENST00000404816 / NM_206943.4; = p.S908L on NM_000627.4) | Missense Mutation (SNP) | VAF 20/125 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.392); catalogued as rs1279563067; called by muse, mutect2, varscan2
- NLRP5 | c.1124C>T p.T375I | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.036); catalogued as rs759848996; called by muse, mutect2, varscan2
- NYAP1 | c.902G>A p.R301H | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0.275); catalogued as rs1291253460, COSV55721719; called by muse, mutect2, varscan2
- PTPRZ1 | c.2903A>G p.H968R | Missense Mutation (SNP) | VAF 11/111 reads (10%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as rs919844024; called by muse, mutect2, varscan2
- PTPRZ1 | c.6546A>C p.E2182D | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.781); catalogued as COSV66442265; called by muse, mutect2, varscan2
- SCN1A | c.4636A>C p.S1546R (on ENST00000303395 / NM_001202435.3; = p.S1535R on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/153 reads (12%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.482); catalogued as CD1211420, COSV57661468; called by muse, mutect2, varscan2
- SMARCA4 | c.4114C>T p.R1372C | Missense Mutation (SNP) | VAF 25/147 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60809056; called by muse, mutect2, varscan2
- TASOR | c.1822C>T p.R608W (on ENST00000355628 / NM_001365636.2; = p.R212W on NM_015224.3) | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.533); catalogued as rs1292382998, COSV62927839; called by muse, mutect2, varscan2
- TMC5 | c.1655G>A p.R552Q (on ENST00000396229 / NM_001105248.1; = p.R306Q on NM_024780.5) | Missense Mutation (SNP) | VAF 25/136 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.216); catalogued as rs753207644, COSV54906844; called by muse, mutect2, varscan2
- TNKS | c.2758G>A p.A920T | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.106); catalogued as rs768679628, COSV60053573, COSV60057144; called by muse, mutect2, varscan2
- TNKS2 | c.1865del p.N622Tfs*29 | Frame Shift Del (DEL) | VAF 12/62 reads (19%) | catalogued as rs749004712; ClinVar: not provided; called by mutect2, varscan2
- TRIM41 | c.1586G>A p.R529H | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as rs777223037, COSV100163260; called by muse, mutect2, varscan2
- UBE3B | c.3082G>A p.G1028S | Missense Mutation (SNP) | VAF 34/161 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.039); catalogued as rs374046452; called by muse, mutect2, varscan2
- ADGRL3 | c.2851G>A p.V951I (on ENST00000506720 / NM_001322402.2; = p.V883I on NM_015236.6) | Missense Mutation (SNP) | VAF 59/401 reads (15%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- AGTR2 | c.304A>C p.T102P | Missense Mutation (SNP) | VAF 49/170 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.571); called by muse, mutect2, varscan2
- APPL1 | c.1519C>A p.L507I | Missense Mutation (SNP) | VAF 22/134 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CD300LB | c.290A>G p.D97G | Missense Mutation (SNP) | VAF 32/198 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- CD83 | c.150_153+30del p.X50_splice | Splice Site (DEL) | VAF 6/48 reads (13%) | called by mutect2, pindel
- CDAN1 | c.2102C>T p.S701F | Missense Mutation (SNP) | VAF 10/184 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CYLD | c.982G>A p.D328N | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DXO | c.134G>A p.R45H | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.623); called by muse, mutect2, varscan2
- DYNC2H1 | c.10841T>G p.L3614R | Missense Mutation (SNP) | VAF 29/137 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.13); called by muse, mutect2
- EBLN2 | c.149A>T p.H50L | Missense Mutation (SNP) | VAF 24/159 reads (15%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- FOLH1 | c.649G>A p.A217T | Missense Mutation (SNP) | VAF 26/184 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GAK | c.1320G>T p.L440F | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.379); called by muse, mutect2, varscan2
- IGHG1 | c.480G>C p.W160C | Missense Mutation (SNP) | VAF 47/248 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGKC | c.10G>A p.A4T | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- IRF5 | c.1337C>T p.S446L | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- KLHL2 | c.1715T>G p.V572G | Missense Mutation (SNP) | VAF 17/141 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.332); called by muse, mutect2, varscan2
- NFKBIE | c.656_659del p.Y219Sfs*25 (on ENST00000275015; = p.Y80Sfs*25 on NM_004556.3) | Frame Shift Del (DEL) | VAF 25/126 reads (20%) | called by pindel, varscan2
- NOL6 | c.1720C>T p.P574S | Missense Mutation (SNP) | VAF 29/155 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- NUBPL | c.844G>T p.E282* | Nonsense Mutation (SNP) | VAF 10/140 reads (7%) | called by muse, mutect2
- POLG | c.2578C>T p.L860F | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RPL27A | c.437T>G p.L146R | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- SHROOM2 | c.791A>G p.K264R | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- SLC24A1 | c.802G>T p.V268F | Missense Mutation (SNP) | VAF 23/175 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- STRAP | c.295C>T p.H99Y | Missense Mutation (SNP) | VAF 43/297 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TCN1 | c.800A>C p.Q267P | Missense Mutation (SNP) | VAF 30/177 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.291); called by muse, mutect2, varscan2
- TNFAIP3 | c.133_140del p.R45Tfs*53 | Frame Shift Del (DEL) | VAF 21/117 reads (18%) | called by mutect2, pindel, varscan2
- TSHR | c.512C>G p.A171G | Missense Mutation (SNP) | VAF 22/183 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.742); called by muse, mutect2, varscan2
- ULK2 | c.2919T>G p.V973= | Splice Region (SNP) | VAF 5/44 reads (11%) | called by muse, mutect2, varscan2
- XIRP2 | c.8376G>C p.E2792D (on ENST00000628543; = p.E2967D on NM_152381.6) | Missense Mutation (SNP) | VAF 28/184 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ZSCAN1 | c.671C>T p.P224L | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ABCA7 | c.5685C>T p.R1895= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as rs771068534, COSV54034743; called by muse, mutect2, varscan2
- ADAMTS2 | c.1815C>T p.Y605= | Silent (SNP) | VAF 22/69 reads (32%) | catalogued as rs369654932; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA2D1 | c.2745A>G p.G915= (on ENST00000356253 / NM_001366867.1; = p.G903= on NM_000722.4) | Silent (SNP) | VAF 9/120 reads (8%) | called by muse, mutect2
- COL4A5 | c.2928A>T p.G976= | Silent (SNP) | VAF 15/42 reads (36%) | catalogued as COSV60362183; called by muse, mutect2, varscan2
- DOK1 | c.534G>A p.V178= | Silent (SNP) | VAF 21/120 reads (18%) | called by muse, mutect2, varscan2
- FAM13A | c.198G>C p.V66= | Silent (SNP) | VAF 16/128 reads (13%) | called by muse, mutect2, varscan2
- FMO1 | c.636C>T p.L212= | Silent (SNP) | VAF 22/153 reads (14%) | called by muse, mutect2, varscan2
- GCLC | c.234G>A p.G78= (on ENST00000643939; = p.G82= on NM_001498.4) | Silent (SNP) | VAF 12/90 reads (13%) | called by muse, mutect2, varscan2
- HTRA1 | c.1095G>A p.T365= | Silent (SNP) | VAF 10/60 reads (17%) | catalogued as rs752097769, COSV64563957; called by muse, mutect2, varscan2
- IGHV2-70 | c.66C>T p.T22= | Silent (SNP) | VAF 26/132 reads (20%) | catalogued as rs368498453; called by muse, mutect2
- IGLV4-3 | c.159A>G p.E53= | Silent (SNP) | VAF 16/93 reads (17%) | catalogued as rs767412920; called by muse, mutect2, varscan2
- ITGA10 | c.3492G>A p.K1164= | Silent (SNP) | VAF 18/154 reads (12%) | called by muse, mutect2, varscan2
- LTA | c.234C>T p.L78= | Silent (SNP) | VAF 48/149 reads (32%) | called by muse, mutect2, varscan2
- PARP14 | c.1809T>C p.V603= | Silent (SNP) | VAF 16/69 reads (23%) | called by muse, mutect2, varscan2
- PLSCR2 | c.267C>T p.Y89= (on ENST00000497985 / NM_001199978.1; = p.Y16= on NM_020359.2) | Silent (SNP) | VAF 11/68 reads (16%) | called by muse, mutect2, varscan2
- SEMA6B | c.591C>T p.T197= | Silent (SNP) | VAF 10/70 reads (14%) | catalogued as rs772842905, COSV56703168; called by muse, mutect2, varscan2
- SF1 | c.1725G>A p.P575= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs760122519, COSV99918812; called by muse, varscan2
- SHC1 | c.1566C>T p.L522= (on ENST00000368445 / NM_183001.5; = p.L413= on NM_003029.5) | Silent (SNP) | VAF 35/267 reads (13%) | called by muse, mutect2, varscan2
- SLC39A12 | c.996C>T p.D332= | Silent (SNP) | VAF 24/147 reads (16%) | called by muse, mutect2, varscan2
- SUN5 | c.858A>G p.S286= | Silent (SNP) | VAF 27/201 reads (13%) | called by muse, mutect2, varscan2
- TRIM54 | c.240G>A p.S80= | Silent (SNP) | VAF 24/177 reads (14%) | catalogued as rs540676343, COSV56081948; called by muse, mutect2, varscan2
- UGT2B4 | c.417A>G p.K139= | Silent (SNP) | VAF 25/147 reads (17%) | called by muse, mutect2, varscan2
- UGT2B4 | c.246T>G p.T82= | Silent (SNP) | VAF 22/136 reads (16%) | called by muse, mutect2, varscan2
- WWTR1 | c.438A>C p.I146= | Silent (SNP) | VAF 14/88 reads (16%) | called by muse, mutect2, varscan2
- ZCCHC7 | c.702C>T p.Y234= | Silent (SNP) | VAF 23/101 reads (23%) | called by muse, mutect2, varscan2
- ZNF653 | c.1599C>T p.C533= | Silent (SNP) | VAF 14/90 reads (16%) | catalogued as rs1320613857, COSV53404648; called by muse, mutect2, varscan2
- C16orf91 | c.*220C>T | 3'UTR (SNP) | VAF 18/130 reads (14%) | catalogued as rs757138439; called by muse, mutect2, varscan2
- PSG5 | c.431-2974T>G | Intron (SNP) | VAF 24/184 reads (13%) | called by muse, mutect2, varscan2
